Somatic mutation profile of tumor specimen TCGA-B8-4620-01A (aliquot TCGA-B8-4620-01A-02D-1386-10) from TCGA case TCGA-B8-4620, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 70.6 years (25,786 days).
Specimen TCGA-B8-4620-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5b1d8b38-7f56-4d5c-b0a1-86fda0ae7d06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-4620-10A (Blood Derived Normal), aliquot TCGA-B8-4620-10A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/acaf22af-3ceb-4cd7-9101-a6372cd0b1f6

The open-access MAF lists 48 somatic variants for this specimen: 43 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Frame Shift Del 7, Silent 3, 3'UTR 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG4 | c.7111G>A p.V2371I | Missense Mutation (SNP) | VAF 71/303 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.883); catalogued as COSV54955935; called by muse, mutect2, varscan2
- AKT1 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.515); catalogued as COSV62573390; called by muse, mutect2, varscan2
- ANAPC1 | c.5363del p.P1788Lfs*10 | Frame Shift Del (DEL) | VAF 69/389 reads (18%) | catalogued as COSV61977905; called by mutect2, pindel, varscan2
- ASH2L | c.778G>T p.D260Y | Missense Mutation (SNP) | VAF 78/304 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51699587; called by muse, mutect2, varscan2
- B2M | c.150del p.H51Ifs*10 | Frame Shift Del (DEL) | VAF 72/256 reads (28%) | catalogued as COSV62563554; called by pindel, varscan2
- BDP1 | c.6638G>T p.G2213V | Missense Mutation (SNP) | VAF 26/371 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV62431348; called by muse, mutect2
- CD55 | c.192A>C p.K64N | Missense Mutation (SNP) | VAF 55/200 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV58576969; called by muse, mutect2, varscan2
- CFHR2 | c.547C>A p.Q183K | Missense Mutation (SNP) | VAF 105/512 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs754703889, COSV66381095; called by muse, mutect2, varscan2
- CLCN7 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.794); catalogued as COSV51970535, COSV99247227; called by muse, mutect2, varscan2
- COBL | c.2704G>C p.V902L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV54345818; called by muse, mutect2, varscan2
- DLK2 | c.908G>T p.G303V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV55087786; called by muse, mutect2, varscan2
- DPYD | c.680G>A p.S227N | Missense Mutation (SNP) | VAF 114/231 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV64597636, COSV64614422; called by muse, mutect2, varscan2
- FAM124A | c.544A>T p.N182Y (on ENST00000322475 / NM_001242312.2; = p.N218Y on NM_145019.4) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs538055450, COSV54476633; called by muse, mutect2
- FANCB | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 79/204 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV60759897; called by muse, mutect2, varscan2
- FLG2 | c.6263G>C p.G2088A | Missense Mutation (SNP) | VAF 300/589 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.714); catalogued as rs762578859, COSV66168681; called by muse, mutect2, varscan2
- IFITM2 | c.223A>C p.I75L | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.119); catalogued as COSV67714633; called by muse, mutect2, varscan2
- IFITM3 | c.226A>C p.I76L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.078); catalogued as COSV67707018; called by muse, varscan2
- IYD | c.547G>C p.E183Q | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.422); catalogued as COSV57601120; called by muse, mutect2, varscan2
- KIR3DL1 | c.1280del p.L427Cfs*51 | Frame Shift Del (DEL) | VAF 128/508 reads (25%) | catalogued as COSV58489912, COSV58491961; called by mutect2, varscan2
- KRTAP20-2 | c.50T>G p.V17G | Missense Mutation (SNP) | VAF 50/347 reads (14%) | PolyPhen benign (0); catalogued as rs8132721, COSV58183315; called by muse, mutect2
- LILRB5 | c.1420C>T p.L474F (on ENST00000449561 / NM_001081442.3; = p.L473F on NM_006840.5) | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.965); catalogued as COSV60257366; called by muse, mutect2, varscan2
- MEOX1 | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV59356163; called by muse, mutect2, varscan2
- MITF | c.491G>A p.G164D (on ENST00000448226 / NM_006722.3; = p.G58D on NM_000248.4) | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV58831478; called by muse, mutect2, varscan2
- MUC16 | c.16789G>A p.V5597M | Missense Mutation (SNP) | VAF 84/179 reads (47%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.025); catalogued as rs751532991, COSV67465644, COSV67474328; called by muse, mutect2, varscan2
- NHSL2 | c.2008A>G p.I670V (on ENST00000510661; = p.I1036V on NM_001013627.2) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as rs1292990423, COSV65452723, COSV65453419; called by muse, mutect2, varscan2
- SACS | c.3957G>C p.K1319N | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.958); catalogued as COSV66539857; called by muse, varscan2
- SACS | c.3956A>C p.K1319T | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.88); catalogued as COSV66539876; called by muse, mutect2, varscan2
- SERPINI1 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 50/327 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55510749; called by muse, mutect2, varscan2
- SGK1 | c.175A>G p.K59E | Missense Mutation (SNP) | VAF 58/202 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV52808398; called by muse, mutect2, varscan2
- STAU2 | c.655C>G p.R219G (on ENST00000524300 / NM_001164380.2; = p.R187G on NM_014393.2) | Missense Mutation (SNP) | VAF 63/323 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV63308147; called by muse, mutect2, varscan2
- STAU2 | c.654G>T p.K218N (on ENST00000524300 / NM_001164380.2; = p.K186N on NM_014393.2) | Missense Mutation (SNP) | VAF 63/331 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63308241, COSV63308680; called by muse, mutect2, varscan2
- SUSD2 | c.476A>C p.E159A | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.7); PolyPhen benign (0.039); catalogued as COSV64203885; called by muse, mutect2, varscan2
- TAB3 | c.2089C>T p.H697Y | Missense Mutation (SNP) | VAF 125/264 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55836949; called by muse, mutect2, varscan2
- TDRD6 | c.2746A>C p.K916Q | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.031); catalogued as COSV60175698; called by muse, mutect2, varscan2
- TRIM41 | c.557G>C p.C186S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV59319096, COSV59319187; called by muse, mutect2, varscan2
- VHL | c.482G>C p.R161P | Missense Mutation (SNP) | VAF 68/106 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM951290, CM961431, COSV104374399, COSV56542648, COSV56545213, COSV56545244; called by muse, mutect2, varscan2
- ADAMTS13 | c.618del p.W206* | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | called by mutect2, varscan2
- EPAS1 | c.2537_2538del p.V846Efs*55 | Frame Shift Del (DEL) | VAF 14/45 reads (31%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.38A>G p.E13G | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); called by muse, varscan2
- LRRC75B | c.398_400dup p.L133dup | In Frame Ins (INS) | VAF 16/59 reads (27%) | called by mutect2, pindel, varscan2
- PBRM1 | c.2500del p.Y834Tfs*21 | Frame Shift Del (DEL) | VAF 116/204 reads (57%) | called by mutect2, pindel, varscan2
- SETD2 | c.5981_5990del p.R1994Nfs*9 | Frame Shift Del (DEL) | VAF 188/309 reads (61%) | called by mutect2, pindel, varscan2
- TGFBRAP1 | c.2029G>T p.G677C | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2
- HACE1 | c.177T>C p.Y59= | Silent (SNP) | VAF 49/147 reads (33%) | catalogued as rs765859242, COSV53502391; called by muse, mutect2, varscan2
- NAP1L3 | c.759A>G p.K253= | Silent (SNP) | VAF 100/468 reads (21%) | catalogued as COSV59075321, COSV59077756; called by muse, mutect2, varscan2
- TNFAIP1 | c.273C>T p.T91= | Silent (SNP) | VAF 45/201 reads (22%) | catalogued as COSV56876651; called by muse, mutect2, varscan2
- C1orf122 | c.*22T>C | 3'UTR (SNP) | VAF 14/34 reads (41%) | catalogued as COSV100888552; called by muse, mutect2, varscan2
- UBTFL2 | n.699C>T | RNA (SNP) | VAF 17/105 reads (16%) | called by muse, mutect2, varscan2
